Somatic mutation profile of tumor specimen 0DH730 from CCDI case PBBUJJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 6.1 years (2,212 days).
Specimen 0DH730: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b9a8be6-4a97-41ec-9c80-af66b8427080.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH6ZV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bafbf3c-55c7-4c0e-ad4b-5508cf91d3c6

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Intron 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.7952G>A p.R2651H | Missense Mutation (SNP) | VAF 543/1210 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200377733; called by muse, mutect2, varscan2
- INPP5J | c.2800C>T p.R934W (on ENST00000331075 / NM_001284285.2; = p.R566W on NM_001002837.2) | Missense Mutation (SNP) | VAF 328/736 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1569291464; called by muse, mutect2, varscan2
- RELN | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 928/2036 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1452632737, COSV59026898; called by muse, mutect2, varscan2
- WASHC4 | c.2207C>T p.T736I | Missense Mutation (SNP) | VAF 631/1411 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs372480465; called by muse, mutect2, varscan2
- ZMIZ1 | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 619/651 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750104148, COSV57903616; called by muse, mutect2, varscan2
- MAZ | c.1214A>T p.Y405F | Missense Mutation (SNP) | VAF 300/1579 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MET | c.2464A>T p.M822L | Missense Mutation (SNP) | VAF 1126/2329 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH11Y | c.778C>G p.Q260E (on ENST00000400457 / NM_032973.2; = p.Q249E on NM_032971.3) | Missense Mutation (SNP) | VAF 117/1788 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2
- PREX1 | c.1155T>A p.D385E | Missense Mutation (SNP) | VAF 925/1924 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- RPL19 | c.548A>T p.E183V | Missense Mutation (SNP) | VAF 81/1622 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2
- SMARCA1 | c.2788A>G p.I930V | Missense Mutation (SNP) | VAF 848/873 reads (97%) | SIFT tolerated (0.28); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- XYLT2 | c.1362C>A p.N454K | Missense Mutation (SNP) | VAF 446/970 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYP11B2 | c.960G>A p.A320= | Silent (SNP) | VAF 514/1068 reads (48%) | catalogued as rs1363331569, COSV100010856; called by muse, mutect2, varscan2
- EFHB | c.1701G>A p.L567= | Silent (SNP) | VAF 693/1617 reads (43%) | called by muse, mutect2, varscan2
- NAGK | c.264C>T p.I88= | Silent (SNP) | VAF 673/1397 reads (48%) | catalogued as rs371544549; called by muse, mutect2, varscan2
- CACNB4 | c.148-88113G>A | Intron (SNP) | VAF 375/803 reads (47%) | catalogued as rs879050699, COSV52394597; called by muse, mutect2, varscan2
- MIR1468 | chrX:63785170 T>A | 3'Flank (SNP) | VAF 596/618 reads (96%) | called by muse, mutect2, varscan2
- PTK7 | c.367+16dup | Intron (INS) | VAF 236/636 reads (37%) | catalogued as rs759460266; called by mutect2, pindel, varscan2
